Gene-level copy-number profile of tumor specimen ALCH-B2CR-TTP1-A from ALCHEMIST case ALCH-B2CR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.4 years (26,813 days).
Specimen ALCH-B2CR-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1cf56585-fe7f-4965-b347-4144cc99e05f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2CR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/ee4ebf70-f03d-4a8f-89c3-b19b35e50bd4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 519; copy number 1: 8,470; copy number 2: 44,290; copy number 3: 5,070; copy number 4: 435; copy number 5: 17; copy number 6: 13; copy number 7: 2; copy number 10: 7; copy number 12: 2; copy number 14: 29; copy number 19: 21; copy number 20: 10; copy number 22: 8; copy number 73: 1; copy number 75: 2; copy number 87: 1; copy number 202: 4.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,620,506–105,626,066, 1 gene (within-gene range 0–2): IGHG4.
- chr14:105,647,924–105,649,057, 1 gene: COPDA1.
- chr15:25,215,541–25,220,578, 3 genes (within-gene range 0–2): SNORD115-25, SNORD115-26, SNORD115-27.
- chr15:25,228,967–25,229,048, 1 gene (within-gene range 0–2): SNORD115-32.
- chr22:18,936,411–18,947,741, 1 gene (within-gene range 0–2): AC007326.5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 117 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,886,304–120,100,779, 4 genes, copy number 10–12: NOTCH2P1, ADAM30, NOTCH2, AC245008.1.
- chr1:149,006,309–149,009,527, 1 gene, copy number 10 (within-gene range 2–10): AC239802.1.
- chr1:149,048,576–149,103,561, 2 genes, copy number 10: AC239804.1, NBPF9.
- chr1:150,293,861–150,913,292, 29 genes, copy number 14: MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3, ARNT, RNU6-1309P, RPS27AP6, CTXND2, CYCSP51.
- chr3:180,989,762–181,836,880, 1 gene, copy number 22 (within-gene range 3–22): SOX2-OT.
- chr3:181,231,737–183,428,778, 37 genes, copy number 19–22: RNU6-4P, FAUP2, AC068308.1, RPL7AP25, AC125613.1, AC125613.2, AC117415.1, SOX2, AC117415.2, RN7SL703P, RNA5SP150, AC007547.2, AC007547.1, LINC01206, RN7SKP265, AC012081.1, AC084211.1, LINC01994, EIF4EP3, LINC01995, AC021055.1, RPL7L1P8, LINC02031, AC083801.1, AC083801.2, AC069431.1, ATP11B, AC069431.2, AC092953.2, DCUN1D1, AC092953.1, MCCC1, MCCC1-AS1, LAMP3, MCF2L2, B3GNT5, RNA5SP151.
- chr8:7,238,286–7,247,571, 2 genes, copy number 7: AF228730.3, OR7E125P.
- chr8:7,295,014–7,298,024, 1 gene, copy number 10: FAM90A20P.
- chr8:126,556,323–127,419,050, 1 gene, copy number 6 (within-gene range 2–202): PCAT1.
- chr8:127,072,694–127,742,951, 10 genes, copy number 5–202: CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC.
- chr16:33,094,204–33,496,093, 16 genes, copy number 5 (within-gene range 2–5): HERC2P8, AC145350.4, AC145350.1, ABHD17AP9, AC138869.1, AC138869.2, TP53TG3C, AC138869.3, AC141257.2, TP53TG3E, AC141257.3, TP53TG3B, AC141257.1, AC141257.4, TP53TG3F, AC136944.5.
- chr16:33,577,502–33,622,547, 1 gene, copy number 6 (within-gene range 3–6): AC142384.1.
- chr19:27,638,483–27,794,005, 4 genes, copy number 6 (within-gene range 4–6): ERVK-28, AC112702.1, LINC00662, AC006504.1.
- chr19:27,802,838–27,898,927, 5 genes, copy number 6 (within-gene range 4–6): AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4.
- chr21:43,461,960–43,479,534, 2 genes, copy number 22–73: LINC00313, AP001048.1.
- chr22:21,125,660–21,128,063, 1 gene, copy number 10: POM121L7P.

Autosomal genes at a single copy (total copy number 1): 7,001. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
